Somatic mutation profile of tumor specimen ALCH-B38F-TTP1-A (aliquot ALCH-B38F-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B38F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.3 years (24,226 days).
Specimen ALCH-B38F-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0250608-4b79-4f14-b39d-d5582286ebc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B38F-NB1-A (Blood Derived Normal), aliquot ALCH-B38F-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83862e25-cba9-47eb-9786-4e4dbd39033e

The open-access MAF lists 98 somatic variants for this specimen: 72 protein-altering or splice-affecting, 19 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 19, Nonsense Mutation 4, 5'UTR 2, Frame Shift Ins 2, Intron 2, RNA 2, 3'UTR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 47/309 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTB | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV59317838; called by muse, mutect2, varscan2
- ADCY7 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs770623244, COSV99576206; called by muse, mutect2, varscan2
- ADGB | c.1680G>T p.L560F | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as rs779396235; called by muse, mutect2, varscan2
- ALAS2 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV58190317; called by muse, mutect2, varscan2
- ANKRD52 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.362); catalogued as COSV57285621; called by muse, mutect2, varscan2
- CSMD3 | c.6147G>C p.L2049F (on ENST00000297405 / NM_001363185.1; = p.L1945F on NM_052900.3) | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV99824027; called by muse, mutect2, varscan2
- EXOC7 | c.2116G>T p.V706L (on ENST00000335146 / NM_001145297.4; = p.V624L on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV58035070; called by muse, mutect2, varscan2
- GIP | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367741847; called by muse, mutect2, varscan2
- KCNK16 | c.68G>A p.C23Y | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs1391884766; called by muse, mutect2, varscan2
- NHLRC2 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758259857; called by muse, mutect2, varscan2
- OR2T12 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 17/158 reads (11%) | catalogued as COSV58776259; called by muse, mutect2
- OR8J3 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV56883156; called by muse, mutect2, varscan2
- PCDHB8 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 86/460 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); catalogued as COSV99177508; called by mutect2, varscan2
- PPP1R3F | c.1414G>T p.V472L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1184111534; called by muse, mutect2
- PTCHD1 | c.466G>T p.V156F | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV65062485; called by muse, mutect2, varscan2
- PTGIR | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775252968, COSV52192829; called by muse, mutect2, varscan2
- RNF208 | c.621C>G p.N207K | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV61288006; called by muse, mutect2, varscan2
- RXFP3 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs376877208; called by muse, mutect2, varscan2
- SGSM1 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68508904; called by muse, mutect2, varscan2
- SYNDIG1 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746007524; called by muse, mutect2
- TAF7L | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 64/406 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as COSV63300024; called by muse, mutect2, varscan2
- TRBV4-2 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 31/488 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs1001004013; called by muse, mutect2
- TTN | c.74485G>A p.G24829R (on ENST00000591111; = p.G17405R on NM_003319.4) | Missense Mutation (SNP) | VAF 28/161 reads (17%) | PolyPhen probably damaging (1); catalogued as COSV60194387; called by muse, mutect2, varscan2
- WDR77 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs774313194; called by muse, mutect2, varscan2
- ZNF134 | c.737A>G p.N246S | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.028); catalogued as rs530039420; called by muse, mutect2, varscan2
- ZNF407 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV99047292; called by muse, mutect2, varscan2
- ZNF850 | c.2169C>A p.H723Q | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs1349829306; called by muse, mutect2, varscan2
- ACSBG1 | c.1236C>A p.N412K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- ADARB1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ADGRG4 | c.8535C>A p.Y2845* | Nonsense Mutation (SNP) | VAF 36/223 reads (16%) | called by muse, mutect2, varscan2
- ADSL | c.563G>C p.R188P | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANKRD31 | c.3002C>G p.S1001* | Nonsense Mutation (SNP) | VAF 39/243 reads (16%) | called by muse, mutect2, varscan2
- ASIC3 | c.1242C>G p.F414L | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- B4GALNT4 | c.2054C>A p.T685K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCNQ | c.113-2A>T p.X38_splice | Splice Site (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
- CD209 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 68/498 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, varscan2
- COIL | c.1687A>T p.I563F | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CTSK | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 63/470 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCBLD1 | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DCDC1 | c.3169G>T p.G1057* (on ENST00000597505 / NM_001367979.1; = p.G164* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 42/266 reads (16%) | called by muse, mutect2, varscan2
- DMD | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 63/433 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DNM3 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- DSEL | c.1562G>C p.C521S | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM170B | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- FOXD4 | c.307dup p.A103Gfs*33 | Frame Shift Ins (INS) | VAF 81/562 reads (14%) | called by mutect2, pindel, varscan2
- FRS2 | c.1267G>C p.D423H | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FRY | c.6088G>T p.D2030Y | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- HERC2 | c.11074A>G p.I3692V | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCTD8 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 47/309 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- KMT2A | c.6523A>G p.I2175V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.1); called by muse, mutect2
- LRRC4C | c.997C>A p.P333T | Missense Mutation (SNP) | VAF 67/362 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO3B | c.2456G>A p.C819Y | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- MYO6 | c.2308A>T p.M770L | Missense Mutation (SNP) | VAF 59/447 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- NAA25 | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.011); called by muse, mutect2
- OR2L13 | c.419G>T p.C140F | Missense Mutation (SNP) | VAF 70/568 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCBP3 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLB1 | c.3412C>G p.H1138D | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRICKLE3 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKD1 | c.1674A>G p.R558= | Splice Region (SNP) | VAF 29/163 reads (18%) | called by muse, mutect2, varscan2
- REPS2 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RET | c.1453G>T p.V485L | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SERBP1 | c.548A>G p.D183G | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- SERGEF | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC7A8 | c.14C>G p.A5G | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SRPX | c.1088A>T p.Q363L | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TGM4 | c.954G>T p.M318I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.166); called by muse, mutect2
- TP63 | c.1338dup p.L447Tfs*15 | Frame Shift Ins (INS) | VAF 48/432 reads (11%) | called by mutect2, pindel, varscan2
- TRBV4-1 | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TRBV4-1 | c.275T>G p.L92R | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC25 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUBB8B | c.63G>T p.W21C | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- AGAP4 | c.936A>T p.T312= | Silent (SNP) | VAF 44/575 reads (8%) | called by muse, mutect2, varscan2
- ALG13 | c.2406A>G p.P802= | Silent (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- CDH12 | c.1380T>C p.I460= | Silent (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- CFAP251 | c.2370C>T p.T790= | Silent (SNP) | VAF 36/204 reads (18%) | catalogued as rs768384403; called by muse, mutect2, varscan2
- DENND4A | c.3510C>T p.L1170= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- DGKD | c.3225T>G p.A1075= (on ENST00000264057 / NM_152879.3; = p.A1031= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/143 reads (15%) | called by muse, varscan2
- DOCK10 | c.237C>T p.D79= | Silent (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- FRY | c.6087G>T p.T2029= | Silent (SNP) | VAF 23/322 reads (7%) | called by muse, mutect2
- GAS1 | c.969C>T p.R323= | Silent (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- GDF5 | c.498C>T p.P166= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as CD016280; called by muse, mutect2
- KIAA1210 | c.3993A>G p.K1331= | Silent (SNP) | VAF 46/299 reads (15%) | catalogued as COSV68179772; called by muse, mutect2, varscan2
- MTUS2 | c.579G>A p.Q193= | Silent (SNP) | VAF 32/179 reads (18%) | catalogued as rs371809914; called by muse, mutect2, varscan2
- MUC12 | c.2112A>C p.T704= (on ENST00000379442; = p.T561= on NM_001164462.1) | Silent (SNP) | VAF 40/207 reads (19%) | called by muse, mutect2, varscan2
- MXRA5 | c.5239C>A p.R1747= | Silent (SNP) | VAF 38/243 reads (16%) | called by muse, mutect2, varscan2
- PIP | c.42C>A p.T14= | Silent (SNP) | VAF 57/287 reads (20%) | called by muse, mutect2, varscan2
- SLC37A2 | c.1368C>A p.P456= | Silent (SNP) | VAF 27/201 reads (13%) | called by muse, mutect2, varscan2
- SLC7A5 | c.1119C>T p.P373= | Silent (SNP) | VAF 20/150 reads (13%) | catalogued as rs746525918, COSV99879138; called by muse, mutect2, varscan2
- SNX6 | c.1048C>T p.L350= (on ENST00000652385; = p.L222= on NM_021249.5) | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- SPATA31D1 | c.471C>A p.S157= | Silent (SNP) | VAF 72/364 reads (20%) | called by muse, mutect2, varscan2
- ALG8 | c.1179-35C>T | Intron (SNP) | VAF 13/111 reads (12%) | catalogued as rs1482703043; called by muse, mutect2, varscan2
- C11orf49 | c.-21T>G | 5'UTR (SNP) | VAF 27/173 reads (16%) | catalogued as rs1247100081; called by muse, mutect2, varscan2
- KRAS | c.*18C>T | 3'UTR (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- MUC19 | n.5643C>A | RNA (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- SNORD115-19 | n.82dup | RNA (INS) | VAF 16/118 reads (14%) | called by mutect2, pindel, varscan2
- ST3GAL5 | c.-26C>G | 5'UTR (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- TECR | c.67-42_67-33del | Intron (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
